Somatic mutation profile of tumor specimen TCGA-FD-A43P-01A (aliquot TCGA-FD-A43P-01A-31D-A23U-08) from TCGA case TCGA-FD-A43P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 74.5 years (27,201 days).
Specimen TCGA-FD-A43P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4540758a-0b03-4f41-99b6-544beddd5cca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A43P-10A (Blood Derived Normal), aliquot TCGA-FD-A43P-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c91b3229-a81a-4266-a619-f1014fa257ff

The open-access MAF lists 445 somatic variants for this specimen: 323 protein-altering or splice-affecting, 115 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 278, Silent 115, Nonsense Mutation 32, Splice Site 5, Splice Region 4, Frame Shift Del 3, 3'UTR 3, Intron 2, 5'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR1A | c.419del p.P140Lfs*4 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs1554888986; ClinVar: pathogenic; called by mutect2, varscan2
- RB1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | hotspot (GDC flag); catalogued as rs121913300, CM941205, COSV57297576, COSV57321266; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV52947834; called by muse, mutect2, varscan2
- ACOX3 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100712063; called by muse, mutect2
- ACP5 | c.587G>T p.R196M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV54536963; called by muse, mutect2, varscan2
- ACSS1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV100053756, COSV100054137; called by muse, mutect2
- ADAMTS9 | c.3967C>T p.R1323C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs561679926, COSV55779122; called by muse, mutect2, varscan2
- ADD1 | c.1764G>C p.E588D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1355733517, COSV53271972; called by muse, mutect2, varscan2
- ADGRE2 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as rs201874467, COSV59695174; called by muse, mutect2, varscan2
- ADGRG6 | c.616A>G p.N206D | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51597184; called by muse, mutect2, varscan2
- AHDC1 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.026); catalogued as rs765209526, COSV55940841; called by muse, mutect2, varscan2
- ALPK2 | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV64494987; called by muse, mutect2, varscan2
- ANKAR | c.3583-1G>C p.X1195_splice | Splice Site (SNP) | VAF 10/82 reads (12%) | catalogued as COSV55615692; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2221C>G p.P741A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV51853844; called by muse, mutect2, varscan2
- ANKRD27 | c.2786A>G p.D929G | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV60134059; called by muse, mutect2, varscan2
- ANKS1A | c.3240G>C p.E1080D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV64462713; called by muse, mutect2, varscan2
- ANPEP | c.2611A>G p.I871V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55593352; called by muse, mutect2, varscan2
- ANXA7 | c.1345-1G>C p.X449_splice (on ENST00000372919 / NM_001320880.2; = p.X427_splice on NM_001156.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV65823129; called by muse, mutect2
- AP1S2 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100236950; called by muse, mutect2
- ARFGEF1 | c.2797C>G p.Q933E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.265); catalogued as COSV51613483, COSV51613615, COSV51619012; called by muse, mutect2, varscan2
- ARHGAP18 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs775258000, COSV63763530; called by muse, mutect2, varscan2
- ARHGAP31 | c.2002G>C p.E668Q | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV51796515; called by muse, mutect2, varscan2
- ARID5A | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV62591405, COSV62591492; called by muse, mutect2, varscan2
- ASH1L | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.935); catalogued as COSV64211181; called by muse, mutect2, varscan2
- ASTN2 | c.2246C>A p.S749Y (on ENST00000313400 / NM_001365069.1; = p.S698Y on NM_014010.5) | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57800430, COSV57824160; called by muse, mutect2, varscan2
- ATG4D | c.860T>A p.L287Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as COSV57265351; called by muse, mutect2, varscan2
- ATM | c.6661G>T p.E2221* | Nonsense Mutation (SNP) | VAF 39/118 reads (33%) | catalogued as COSV53759724, COSV99592221; called by muse, mutect2, varscan2
- ATMIN | c.1425G>C p.Q475H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100214793; called by muse, mutect2, varscan2
- ATP11A | c.2399C>T p.A800V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV52118139; called by muse, mutect2, varscan2
- ATP11A | c.2852A>G p.Y951C | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52118158; called by muse, mutect2, varscan2
- ATP2A1 | c.2408C>T p.P803L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV62870315; called by muse, mutect2, varscan2
- ATP8A2 | c.1718G>A p.R573K | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV54966222; called by muse, mutect2, varscan2
- ATP8B4 | c.1762T>G p.F588V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV52721558, COSV99467788; called by muse, mutect2
- B3GNT8 | c.657C>G p.F219L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV54198648; called by mutect2, varscan2
- BAMBI | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.978); catalogued as COSV65003270; called by muse, mutect2, varscan2
- BRCA2 | c.2573G>C p.R858T | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66458676; called by muse, mutect2
- BRCA2 | c.9778G>C p.D3260H | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV66337748; called by muse, mutect2
- BSN | c.9685C>G p.R3229G | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56515725; called by muse, mutect2
- C19orf44 | c.881C>G p.S294* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as rs150685247, COSV99685503; called by muse, mutect2, varscan2
- C2orf16 | c.5089C>A p.P1697T | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.647); catalogued as COSV100820805, COSV62677196; called by muse, varscan2
- C2orf16 | c.5203C>T p.H1735Y | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.182); catalogued as COSV62677199; called by muse, varscan2
- C6 | c.1033C>A p.L345M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54714186, COSV54714253; called by muse, mutect2, varscan2
- C6orf89 | c.135G>C p.K45N (on ENST00000373685; = p.K52N on NM_152734.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV62102592; called by muse, mutect2, varscan2
- CACNA2D4 | c.2410C>A p.Q804K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV54955574; called by muse, mutect2, varscan2
- CARMIL1 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs1465048538, COSV100278929; called by muse, mutect2
- CASR | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56139617; called by muse, mutect2, varscan2
- CBX4 | c.1662C>A p.F554L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV53966628; called by muse, mutect2, varscan2
- CCDC88B | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV57267224; called by muse, mutect2, varscan2
- CCDC88B | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as COSV57267228; called by muse, mutect2, varscan2
- CCDC88B | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.261); catalogued as COSV57264792, COSV57267232; called by muse, mutect2, varscan2
- CCHCR1 | c.1863G>T p.R621S | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV52548541; called by muse, mutect2, varscan2
- CCNT2 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV51475076; called by muse, mutect2, varscan2
- CD2BP2 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs775874982, COSV59767989, COSV59769054, COSV59769344; called by muse, mutect2, varscan2
- CDC42 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV59662771; called by muse, mutect2, varscan2
- CENPU | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.762); catalogued as COSV55658571; called by muse, mutect2, varscan2
- CHCHD2 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101271062; called by muse, mutect2, varscan2
- CHD7 | c.664C>G p.Q222E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as CM163546, COSV71113011, COSV71114134; called by muse, mutect2, varscan2
- CHGB | c.1406G>C p.R469T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV66759946, COSV66761313; called by muse, mutect2, varscan2
- CHGB | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV66761317; called by muse, mutect2, varscan2
- CHRNA5 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.453); catalogued as rs143586773; called by muse, mutect2, varscan2
- CHRNB1 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1389864432, COSV60141413; called by muse, mutect2, varscan2
- CIC | c.4133C>T p.S1378F | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV50633283; called by muse, mutect2
- CLSTN2 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV101515939; called by muse, mutect2, varscan2
- CMSS1 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV70439924; called by muse, mutect2, varscan2
- CNTNAP2 | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV62225013, COSV62272373; called by muse, mutect2, varscan2
- COBLL1 | c.2043G>C p.Q681H (on ENST00000392717; = p.Q643H on NM_014900.5) | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52072445; called by muse, mutect2, varscan2
- COL5A2 | c.4381G>A p.V1461I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100880885, COSV99058932; called by muse, mutect2
- COQ8B | c.1156G>C p.D386H | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54688105; called by muse, mutect2
- CPAMD8 | c.2875C>G p.H959D (on ENST00000651564; = p.H912D on NM_015692.5) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.225); catalogued as COSV71597023; called by muse, mutect2, varscan2
- CPLX3 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs1465998989, COSV59002831; called by muse, mutect2, varscan2
- CRISP1 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV59994627; called by muse, mutect2, varscan2
- CRISP3 | c.107C>T p.P36L (on ENST00000371159 / NM_001368123.1; = p.P18L on NM_006061.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV53822013, COSV53822836; called by muse, mutect2, varscan2
- CSMD3 | c.4648G>A p.V1550I (on ENST00000297405 / NM_001363185.1; = p.V1446I on NM_052900.3) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as COSV52256120; called by muse, mutect2, varscan2
- CSPG4 | c.5911G>A p.D1971N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.714); catalogued as COSV57898943; called by muse, mutect2
- CST9L | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.858); catalogued as COSV100980831, COSV100980916; called by muse, mutect2
- CXCL2 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1340840344, COSV56021894; called by muse, mutect2, varscan2
- CYLC1 | c.841A>G p.T281A | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated, low confidence (0.65); catalogued as COSV100255572; called by muse, mutect2, varscan2
- CYP3A43 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV55937156; called by muse, mutect2, varscan2
- DCP2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as COSV66617772; called by muse, mutect2, varscan2
- DCP2 | c.1075A>G p.K359E | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.138); catalogued as COSV66617783; called by muse, mutect2, varscan2
- DENND5A | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as rs61877790, COSV60236323; called by muse, mutect2, varscan2
- DENND5A | c.2088G>A p.W696* | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | catalogued as rs1554916561, COSV100065295; called by muse, varscan2
- DHCR7 | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV62796035; called by muse, mutect2
- DNA2 | c.1210C>G p.L404V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.64); catalogued as COSV64429469; called by muse, mutect2
- DNAH8 | c.4687G>A p.E1563K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59466558; called by muse, mutect2, varscan2
- DROSHA | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100757841; called by muse, mutect2, varscan2
- DUOXA2 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV50994162; called by muse, mutect2, varscan2
- DUSP10 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs767852820, COSV60457247, COSV60458990; called by muse, mutect2, varscan2
- DYNC1H1 | c.6877G>C p.G2293R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64139803; called by muse, mutect2, varscan2
- E2F8 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV51465024; called by muse, mutect2, varscan2
- ECH1 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.228); catalogued as rs1341091280, COSV55489839; called by muse, mutect2
- EDNRB | c.724G>A p.V242I (on ENST00000377211 / NM_001201397.1; = p.V152I on NM_000115.5) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57518884; called by muse, mutect2, varscan2
- ELF3 | c.795G>C p.K265N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV62839444; called by muse, mutect2, varscan2
- ENSA | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as COSV55027214; called by muse, mutect2
- EPHA5 | c.1682C>A p.P561Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.381); catalogued as COSV56639209, COSV99900172; called by muse, mutect2, varscan2
- EPS8L3 | c.126G>C p.Q42H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV62610083; called by muse, mutect2, varscan2
- EXOSC9 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV54667149; called by muse, mutect2
- F13A1 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53562411, COSV99344101; called by muse, mutect2
- FAM86B1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.631); catalogued as rs566042650; called by mutect2, varscan2
- FAM91A1 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58238405; called by muse, mutect2, varscan2
- FARP2 | c.2959G>A p.D987N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1012198713, COSV50875918; called by muse, mutect2, varscan2
- FAT4 | c.7120C>T p.P2374S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs749817883, COSV58698831; called by muse, mutect2, varscan2
- FAT4 | c.11246C>A p.A3749D | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV58698851; called by muse, mutect2, varscan2
- FAT4 | c.12508C>T p.R4170C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs540573222, COSV58698871; called by muse, mutect2, varscan2
- FBXW2 | c.1230G>C p.K410N | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV61597623; called by muse, mutect2, varscan2
- FIP1L1 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV60998440; called by muse, mutect2, varscan2
- FLAD1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52698488; called by muse, mutect2, varscan2
- FLG2 | c.3718C>T p.H1240Y | Missense Mutation (SNP) | VAF 213/340 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV66171070; called by muse, mutect2, varscan2
- FLNC | c.7372G>T p.E2458* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100368861; called by muse, varscan2
- FOCAD | c.3892A>G p.I1298V | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV58104420; called by muse, mutect2, varscan2
- FPGS | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV64676009; called by muse, mutect2, varscan2
- FRAS1 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53630363; called by muse, mutect2, varscan2
- GAB1 | c.2013G>C p.K671N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53758957; called by muse, varscan2
- GDE1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV62059213, COSV62059751; called by muse, mutect2, varscan2
- GHRL | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55056138; called by muse, mutect2
- GLRX3 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as rs769979468, COSV100487987; called by muse, mutect2, varscan2
- GPNMB | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1236146268, COSV51698036, COSV51700439; called by muse, mutect2, varscan2
- GPRIN3 | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV60885690; called by muse, mutect2, varscan2
- GRIPAP1 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.99); catalogued as COSV100904398; called by muse, mutect2, varscan2
- GRM1 | c.1906G>C p.A636P | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51213199; called by muse, mutect2, varscan2
- GRM5 | c.2757G>C p.Q919H (on ENST00000305447 / NM_001143831.2; = p.Q887H on NM_000842.4) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV59617313; called by muse, mutect2, varscan2
- GRM5 | c.518C>G p.S173* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100551268, COSV100554780, COSV59621424; called by muse, mutect2, varscan2
- GSS | c.1029G>A p.V343= | Splice Region (SNP) | VAF 6/55 reads (11%) | catalogued as COSV53626823; called by muse, mutect2, varscan2
- H2BC9 | c.140A>G p.K47R | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.176); catalogued as rs200294518, COSV55100470; called by muse, varscan2
- H3C3 | c.118C>G p.H40D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as COSV63551299, COSV63551685; called by muse, varscan2
- HAPLN1 | c.790C>G p.L264V | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV57150323; called by muse, mutect2
- HELZ | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.573); catalogued as COSV62379810; called by muse, mutect2, varscan2
- HGS | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs746231981, COSV61268291; called by muse, mutect2, varscan2
- HIF1AN | c.627G>C p.Q209H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as COSV54501375; called by muse, mutect2, varscan2
- HINFP | c.1503C>G p.I501M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV63432400; called by muse, varscan2
- HMCN1 | c.3828A>C p.Q1276H | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54922025; called by muse, mutect2, varscan2
- HNRNPUL1 | c.704C>G p.T235R | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV54565093; called by muse, mutect2
- HPN | c.740G>C p.R247P | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.785); catalogued as COSV52884943; called by muse, mutect2
- HSPA12A | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV65023257; called by muse, mutect2, varscan2
- IGSF3 | c.3270G>T p.Q1090H (on ENST00000369486 / NM_001007237.3; = p.Q1110H on NM_001542.4) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV59595440; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV100151047; called by muse, mutect2
- IL20RB | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59048810; called by muse, mutect2, varscan2
- IMPG2 | c.2551C>T p.Q851* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as COSV99516628; called by muse, mutect2, varscan2
- INTS13 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV53904259; called by muse, mutect2, varscan2
- IRX5 | c.1204C>G p.L402V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.211); catalogued as rs952903879, COSV100316032; called by muse, mutect2
- ISG20L2 | c.384G>C p.K128N | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); catalogued as COSV57460504; called by muse, mutect2, varscan2
- ITPKB | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99685285; called by muse, mutect2, varscan2
- JPH2 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1302891529, COSV65904731; called by muse, mutect2
- KANK1 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63214044; called by muse, mutect2, varscan2
- KIAA2013 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as COSV100927157; called by muse, mutect2
- KIF5B | c.2667del p.R890Vfs*10 | Frame Shift Del (DEL) | VAF 22/186 reads (12%) | catalogued as COSV56654592; called by mutect2, pindel, varscan2
- KLC3 | c.1235-2A>G p.X412_splice | Splice Site (SNP) | VAF 25/173 reads (14%) | catalogued as COSV67269368; called by muse, mutect2, varscan2
- KLHDC4 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs769964523, COSV54510126; called by muse, mutect2, varscan2
- KLHL38 | c.1325T>A p.M442K | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV58088427; called by muse, mutect2, varscan2
- KMT2C | c.7520G>A p.G2507E | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.541); catalogued as COSV51473308; called by muse, mutect2, varscan2
- KRIT1 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100388964; called by muse, mutect2
- KRT33B | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs921874412, COSV52441790; called by muse, mutect2, varscan2
- KRTAP10-3 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs373472330; called by muse, mutect2, varscan2
- LIPF | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV53285315; called by muse, mutect2, varscan2
- LIPF | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768207904, COSV53285330; called by muse, mutect2, varscan2
- LNPK | c.152C>G p.S51* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99770512; called by muse, mutect2, varscan2
- LRP2 | c.9070G>A p.E3024K | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55564706; called by muse, mutect2
- LSM14A | c.608C>G p.S203* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | catalogued as COSV101471760; called by muse, mutect2, varscan2
- LTF | c.318G>A p.Q106= | Splice Region (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99212200; called by muse, mutect2, varscan2
- MAGOH | c.89-1G>A p.X30_splice | Splice Site (SNP) | VAF 11/83 reads (13%) | catalogued as COSV65161372; called by muse, mutect2, varscan2
- MAP3K19 | c.3449G>C p.S1150T | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59640858; called by muse, mutect2, varscan2
- MAP3K9 | c.2368G>T p.E790* (on ENST00000554752 / NM_001284230.1; = p.E804* on NM_033141.4) | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV101173784; called by muse, mutect2, varscan2
- MC1R | c.771C>G p.F257L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.181); catalogued as COSV59626230; called by muse, mutect2, varscan2
- MCF2L2 | c.2905G>C p.E969Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.36); catalogued as COSV61049123; called by muse, mutect2, varscan2
- MCM3AP | c.3232G>A p.E1078K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs771466046, COSV52437070; called by muse, mutect2
- MCOLN1 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 19/131 reads (15%) | catalogued as COSV99900940; called by muse, mutect2, varscan2
- MRPL57 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53436130; called by muse, mutect2, varscan2
- MRPS31 | c.137C>A p.S46* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100062541; called by muse, mutect2, varscan2
- MUC16 | c.21715G>C p.E7239Q | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.047); catalogued as COSV67446391, COSV67480734; called by muse, mutect2, varscan2
- MUC17 | c.1758G>C p.E586D | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV60286818, COSV60296943; called by muse, mutect2, varscan2
- MYH2 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761461325, COSV55443801; called by muse, mutect2, varscan2
- MYLK3 | c.2409C>G p.F803L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV67365640; called by muse, mutect2, varscan2
- NAA38 | c.197G>C p.C66S (on ENST00000575771 / NM_001320925.2; = p.C114S on NM_032356.5) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV54684471; called by muse, mutect2, varscan2
- NAALADL1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752886257, COSV60523012; called by muse, mutect2, varscan2
- NAXE | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1048284296, COSV58040887; called by muse, mutect2, varscan2
- NBPF1 | c.2231A>T p.D744V | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99844987; called by mutect2, varscan2
- NCOR1 | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.398); catalogued as COSV51986400; called by muse, mutect2, varscan2
- NLRP3 | c.591del p.V198* | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as COSV100275341; called by mutect2, pindel
- NLRP3 | c.1798C>T p.Q600* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV60230656; called by muse, mutect2, varscan2
- NOBOX | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV56196278; called by muse, mutect2, varscan2
- NOVA1 | c.692G>C p.R231P | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV57482986; called by muse, mutect2, varscan2
- NPC1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs201021988; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPTX2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55718339; called by muse, mutect2, varscan2
- NRAS | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs746572499, COSV54754070; called by muse, mutect2, varscan2
- NSMAF | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as COSV50694106; called by muse, mutect2, varscan2
- NSMAF | c.687G>A p.P229= | Splice Region (SNP) | VAF 11/47 reads (23%) | catalogued as rs760741647, COSV50694192; called by muse, mutect2, varscan2
- NUP210 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV54410240; called by muse, mutect2
- OBSL1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750505464, COSV54725814; called by muse, mutect2, varscan2
- OGG1 | c.671G>A p.W224* | Nonsense Mutation (SNP) | VAF 22/37 reads (59%) | catalogued as COSV99844991; called by muse, mutect2, varscan2
- OR2J3 | c.871C>G p.L291V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as COSV65849422, COSV65849852; called by muse, mutect2, varscan2
- OR2T4 | c.336G>T p.K112N | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV63544665; called by muse, mutect2, varscan2
- OR4A16 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as COSV59043820; called by muse, mutect2, varscan2
- OR5M1 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777012897, COSV101591616; called by muse, mutect2, varscan2
- PANK4 | c.291G>C p.E97D | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV65867412; called by muse, mutect2, varscan2
- PAPOLA | c.1816C>A p.P606T | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.1); catalogued as COSV53483679; called by muse, mutect2, varscan2
- PARP11 | c.663G>C p.W221C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.187); catalogued as COSV57396429; called by muse, mutect2, varscan2
- PAX7 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV64748729; called by muse, mutect2, varscan2
- PCDHA1 | c.1663G>T p.V555L | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100974636, COSV65375836; called by muse, mutect2, varscan2
- PCDHA6 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV65346125; called by muse, mutect2, varscan2
- PCDHGA4 | c.1948G>A p.V650M | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53993901; called by muse, mutect2, varscan2
- PCDHGC3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52746158, COSV99038133; called by muse, mutect2, varscan2
- PDSS2 | c.905A>T p.K302I | Missense Mutation (SNP) | VAF 422/815 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as rs1335485456, COSV64656436; called by muse, mutect2, varscan2
- PEAK1 | c.908G>A p.R303K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs771512988, COSV56934620, COSV56940026; called by muse, mutect2, varscan2
- PFAS | c.3265G>C p.E1089Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV58982086; called by muse, mutect2, varscan2
- PHLDB2 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 71/197 reads (36%) | catalogued as COSV101208742; called by muse, mutect2, varscan2
- PI4KB | c.1342A>G p.T448A (on ENST00000368873 / NM_001369623.1; = p.T460A on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV55019828; called by muse, mutect2, varscan2
- PIBF1 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58326213; called by muse, mutect2, varscan2
- PKHD1L1 | c.11201C>T p.P3734L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV65741959, COSV65748452; called by muse, mutect2, varscan2
- PLAA | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs1460168098, COSV68305333; called by muse, mutect2, varscan2
- PLCB3 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV54190785; called by muse, mutect2, varscan2
- PLEKHH2 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56757971; called by muse, mutect2, varscan2
- PNPLA1 | c.572C>G p.S191C (on ENST00000394571 / NM_001374623.1; = p.S96C on NM_173676.2) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV57236411; called by muse, mutect2, varscan2
- POLE3 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV55913437; called by muse, mutect2, varscan2
- POLR1F | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs527876640, COSV55999170; called by muse, mutect2, varscan2
- PPP1R3A | c.2233T>C p.S745P | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs1280065532, COSV52888218; called by muse, mutect2, varscan2
- PPP4R1 | c.1456G>T p.E486* (on ENST00000400556 / NM_001042388.3; = p.E469* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99554044; called by muse, mutect2, varscan2
- PPTC7 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62826211, COSV62826723; called by muse, mutect2, varscan2
- PSMC3 | c.785G>C p.G262A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54082007; called by muse, mutect2, varscan2
- PTPRO | c.1472C>G p.S491* | Nonsense Mutation (SNP) | VAF 19/74 reads (26%) | catalogued as COSV99841904; called by muse, mutect2, varscan2
- PTPRO | c.2530C>G p.L844V | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV55517034; called by muse, mutect2, varscan2
- PTPRT | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); catalogued as COSV61972174; called by muse, varscan2
- PYGM | c.1433A>G p.H478R | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs758131128, COSV51222599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- R3HDM1 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51529197; called by muse, varscan2
- R3HDM1 | c.1591C>G p.Q531E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as COSV51529209; called by muse, varscan2
- RECQL | c.623A>T p.Y208F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.355); catalogued as COSV59085433; called by muse, mutect2, varscan2
- RECQL5 | c.2429G>C p.G810A | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.468); catalogued as COSV58643734; called by muse, mutect2, varscan2
- RFX5 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99303354; called by muse, mutect2
- RNF123 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1418646227, COSV59690440; called by muse, varscan2
- RPL37 | c.6G>A p.T2= | Splice Region (SNP) | VAF 7/69 reads (10%) | catalogued as rs780838417, COSV57038839; called by muse, mutect2, varscan2
- RPS12 | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV57767544; called by muse, mutect2, varscan2
- RPS13 | c.143C>A p.S48* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as COSV99930618; called by muse, mutect2, varscan2
- RUFY3 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV56915822; called by muse, mutect2, varscan2
- RUNX1 | c.389G>C p.R130T (on ENST00000344691 / NM_001001890.3; = p.R157T on NM_001754.5) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55871984, COSV55885034; called by muse, mutect2, varscan2
- RYR1 | c.2014C>A p.P672T | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV62104318; called by muse, mutect2
- SCARA3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.137); catalogued as rs528248820, COSV57271080; called by muse, mutect2, varscan2
- SCN10A | c.506T>G p.L169W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV71862291, COSV71862727; called by muse, mutect2, varscan2
- SCO1 | c.73C>A p.R25S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV55135722, COSV99703635; called by muse, mutect2
- SEMA3A | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54880819; called by muse, mutect2, varscan2
- SEMA3A | c.382C>G p.H128D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54880829; called by muse, mutect2, varscan2
- SEPTIN1 | c.1055G>C p.R352P (on ENST00000321367; = p.R305P on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV58441870, COSV58443034; called by muse, mutect2, varscan2
- SH3BP4 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60645266; called by muse, mutect2, varscan2
- SH3RF1 | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.089); catalogued as rs1170477242, COSV52923247; called by muse, mutect2
- SH3RF2 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63040392; called by muse, mutect2, varscan2
- SHARPIN | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs777839426, COSV59363090; called by muse, mutect2, varscan2
- SI | c.2626C>T p.Q876* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | catalogued as COSV100016264; called by muse, mutect2
- SIRPB1 | c.1070C>G p.S357* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV99498620; called by muse, mutect2, varscan2
- SLC16A1 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV63709957; called by muse, mutect2, varscan2
- SLC22A9 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs773707960, COSV54167925, COSV54168811; called by muse, mutect2, varscan2
- SLC23A3 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.372); catalogued as COSV55408755; called by muse, mutect2, varscan2
- SLC25A2 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53403028; called by muse, mutect2, varscan2
- SLC2A12 | c.970G>T p.G324* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as COSV99260660; called by muse, mutect2
- SLC66A2 | c.411C>G p.F137L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60844173; called by muse, mutect2, varscan2
- SLCO1C1 | c.691G>T p.V231F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs1221692894, COSV56873256, COSV99859348; called by muse, mutect2, varscan2
- SMU1 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV68140157; called by muse, mutect2, varscan2
- SP1 | c.1574C>G p.S525C (on ENST00000327443 / NM_138473.3; = p.S518C on NM_003109.1) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); catalogued as COSV59404368; called by muse, mutect2, varscan2
- SPRY3 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57143753; called by muse, mutect2, varscan2
- SPTB | c.6832T>A p.S2278T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV55981922; called by muse, mutect2, varscan2
- SSU72P8 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV66361268; called by muse, mutect2, varscan2
- STK3 | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398850890, COSV69225618, COSV69226334; called by muse, mutect2, varscan2
- STS | c.771G>C p.Q257H | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.205); catalogued as COSV54270379; called by muse, mutect2, varscan2
- SULT1C4 | c.394-1G>C p.X132_splice | Splice Site (SNP) | VAF 22/108 reads (20%) | catalogued as rs780747979, COSV55598451; called by muse, mutect2, varscan2
- SUPT20H | c.1999G>C p.E667Q (on ENST00000350612 / NM_001014286.3; = p.E668Q on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.214); catalogued as COSV53509724; called by muse, mutect2, varscan2
- SYNDIG1 | c.504G>C p.E168D | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs1262202628, COSV65237694; called by muse, mutect2, varscan2
- SYNE1 | c.3093C>A p.F1031L (on ENST00000367255 / NM_182961.4; = p.F1038L on NM_033071.3) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV55045202; called by muse, mutect2, varscan2
- SYTL5 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs867175501, COSV52903338; called by muse, mutect2, varscan2
- TAS2R7 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.145); catalogued as COSV53690079, COSV99553809; called by muse, mutect2, varscan2
- TAS2R8 | c.318C>G p.F106L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53690087; called by muse, mutect2, varscan2
- TBC1D15 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV59851343; called by muse, mutect2, varscan2
- TBRG1 | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52516272; called by muse, mutect2, varscan2
- THEMIS | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV64072867; called by muse, mutect2, varscan2
- TM9SF3 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575129837, COSV64458048; called by muse, mutect2, varscan2
- TMC4 | c.1375G>T p.E459* (on ENST00000617472 / NM_001145303.3; = p.E453* on NM_144686.4) | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV55826351; called by muse, mutect2, varscan2
- TMEM222 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs762890759, COSV65027378; called by muse, mutect2, varscan2
- TMEM87B | c.1475C>G p.S492* | Nonsense Mutation (SNP) | VAF 26/220 reads (12%) | catalogued as rs939804994, COSV51712558, COSV51716527, COSV99314699; called by muse, varscan2
- TMIGD1 | c.12G>C p.K4N | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100187390; called by muse, mutect2
- TNRC6A | c.4598C>G p.S1533* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100170527; called by muse, mutect2, varscan2
- TOP1 | c.1930A>T p.M644L | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV63695152; called by muse, mutect2, varscan2
- TP53 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV52663871, COSV53107584, COSV53160330, COSV53724059; called by muse, mutect2, varscan2
- TRABD2A | c.1181C>G p.S394* (on ENST00000409520 / NM_001277053.2; = p.S345* on NM_001080824.3) | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99409003; called by muse, mutect2, varscan2
- TRAM2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.67); catalogued as COSV51733968; called by muse, mutect2
- TRIM15 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV64990044; called by muse, mutect2, varscan2
- TRIM29 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV59281535; called by muse, mutect2, varscan2
- TRMT10B | c.644C>G p.S215* | Nonsense Mutation (SNP) | VAF 21/174 reads (12%) | catalogued as COSV99956239; called by muse, mutect2, varscan2
- TTC16 | c.2034G>C p.Q678H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV60161637; called by muse, mutect2, varscan2
- TTC21A | c.2906G>C p.R969T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57187697; called by muse, mutect2, varscan2
- TTN | c.7288C>G p.P2430A (on ENST00000591111; = p.P2384A on NM_003319.4) | Missense Mutation (SNP) | VAF 19/117 reads (16%) | PolyPhen possibly damaging (0.54); catalogued as COSV60214413; called by muse, mutect2, varscan2
- TXNIP | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV65220949; called by muse, mutect2, varscan2
- UACA | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100537816; called by muse, mutect2, varscan2
- UHRF2 | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV52794702; called by muse, mutect2, varscan2
- UTP25 | c.1590G>C p.Q530H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71966082; called by muse, mutect2, varscan2
- UTRN | c.4453T>G p.L1485V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62342154; called by muse, mutect2, varscan2
- VPS13A | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.755); catalogued as COSV62429395, COSV62434500; called by muse, mutect2
- VPS13C | c.9992C>G p.S3331C (on ENST00000644861 / NM_020821.3; = p.S3288C on NM_017684.5) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99830444; called by muse, mutect2
- WBP11 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53763893; called by muse, mutect2, varscan2
- WDR62 | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as COSV54337553; called by muse, mutect2
- WDR81 | c.4111G>A p.E1371K (on ENST00000409644 / NM_001163809.2; = p.E320K on NM_152348.4) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV100489295; called by muse, mutect2
- WNK3 | c.5099C>T p.T1700I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1557140917, COSV63615154; called by muse, mutect2, varscan2
- WNT3 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 58/77 reads (75%) | catalogued as rs1335027382, COSV56645856; called by muse, mutect2, varscan2
- WNT3A | c.257G>A p.W86* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as COSV99470243; called by muse, mutect2, varscan2
- XPO7 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV53017678; called by muse, varscan2
- XXYLT1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs376617200; called by muse, mutect2, varscan2
- YIPF2 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99450371; called by muse, mutect2
- ZC3H15 | c.194C>A p.A65D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV61923169; called by muse, mutect2, varscan2
- ZC3H6 | c.3478A>G p.T1160A | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV59669539; called by muse, mutect2, varscan2
- ZCCHC13 | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59866509; called by muse, mutect2
- ZDHHC20 | c.70T>C p.F24L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57187517; called by muse, mutect2
- ZIK1 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.636); catalogued as rs149356470; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1583G>A p.R528K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV52853550; called by muse, mutect2
- ZNF10 | c.1034G>C p.G345A | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV50213687; called by muse, mutect2, varscan2
- ZNF155 | c.268C>G p.P90A | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs753145596, COSV54207906; called by muse, mutect2
- ZNF17 | c.802C>G p.H268D | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1280547268, COSV56920692, COSV56921987; called by muse, mutect2, varscan2
- ZNF235 | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV52157634; called by muse, mutect2
- ZNF25 | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56923462; called by muse, mutect2, varscan2
- ZNF285 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.861); catalogued as COSV58410159; called by muse, mutect2
- ZNF423 | c.1457C>T p.S486F (on ENST00000563137 / NM_001379286.1; = p.S478F on NM_015069.4) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs1178606806, COSV52198548, COSV99284221; called by muse, mutect2, varscan2
- ZNF567 | c.689G>C p.R230T (on ENST00000536254 / NM_001322913.1; = p.R199T on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV100659012; called by muse, mutect2
- ZNF569 | c.1093C>A p.Q365K | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.835); catalogued as COSV57596300, COSV57597519; called by muse, mutect2
- ZNF790 | c.1079A>G p.H360R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63212939; called by muse, mutect2, varscan2
- ZPBP2 | c.428C>T p.S143L (on ENST00000348931 / NM_199321.3; = p.S121L on NM_198844.3) | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.437); catalogued as rs867409751, COSV62375485; called by muse, mutect2, varscan2
- ZSWIM1 | c.1340C>A p.T447N | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV54849740; called by muse, mutect2
- KDM6A | c.2196_2197dup p.H733Rfs*23 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- LYZL6 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- OR6B2 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.06); called by muse, mutect2
- ABCA12 | c.4092C>G p.L1364= (on ENST00000272895 / NM_173076.3; = p.L1046= on NM_015657.3) | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV55968717; called by muse, mutect2, varscan2
- ACTR1B | c.345C>G p.L115= | Silent (SNP) | VAF 17/166 reads (10%) | catalogued as COSV56705147; called by muse, mutect2, varscan2
- AGT | c.801G>T p.L267= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV64184484, COSV64185136; called by muse, mutect2, varscan2
- ARVCF | c.246G>A p.T82= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV54268527; called by muse, mutect2, varscan2
- ASRGL1 | c.684G>A p.V228= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV57125665; called by muse, mutect2
- ATMIN | c.1647G>A p.Q549= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV55146989; called by muse, mutect2, varscan2
- ATP13A3 | c.1353A>G p.T451= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as COSV55467507; called by muse, mutect2, varscan2
- AUP1 | c.138G>A p.G46= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99239985; called by muse, mutect2
- BRINP3 | c.1692C>T p.T564= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs779155067, COSV66533283; called by muse, mutect2, varscan2
- BUB1 | c.484C>T p.L162= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs765969185, COSV57065556; called by muse, mutect2, varscan2
- CADM4 | c.192C>G p.L64= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as COSV55929502; called by muse, mutect2
- CBX4 | c.1206C>T p.V402= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs771797783, COSV99490612; called by muse, varscan2
- CDRT1 | c.1119G>A p.T373= | Silent (SNP) | VAF 37/169 reads (22%) | catalogued as rs770002212, COSV55412683; called by muse, mutect2, varscan2
- CHD6 | c.6624C>G p.L2208= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV64692981; called by muse, mutect2, varscan2
- CHD7 | c.792C>A p.L264= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV71113014; called by muse, mutect2, varscan2
- CHRDL2 | c.162C>A p.G54= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV99734147; called by muse, varscan2
- CHRNA3 | c.423C>G p.L141= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV58776389; called by muse, mutect2, varscan2
- CHRNA9 | c.750C>G p.L250= | Silent (SNP) | VAF 53/325 reads (16%) | catalogued as COSV59575332; called by muse, mutect2, varscan2
- CHTF8 | c.312C>A p.I104= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV54708324; called by muse, varscan2
- CNTRL | c.3108C>T p.L1036= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV53045566; called by muse, mutect2, varscan2
- COL16A1 | c.789C>A p.L263= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV54710812, COSV54715267; called by muse, mutect2, varscan2
- COL4A4 | c.1095C>G p.L365= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs1410008498, COSV61630353; called by muse, mutect2, varscan2
- CORO1A | c.444C>T p.L148= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV54631760; called by muse, varscan2
- CPNE3 | c.1020G>A p.K340= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99548157; called by muse, mutect2
- CPTP | c.486C>T p.F162= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100028703; called by muse, mutect2
- CRLF3 | c.936C>T p.F312= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as COSV60836654; called by muse, mutect2
- CRNKL1 | c.279G>A p.K93= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1441231867, COSV99846804; called by muse, mutect2
- CTSS | c.783C>A p.L261= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV64566720; called by muse, mutect2
- DCP2 | c.501C>T p.I167= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV66617779; called by muse, mutect2, varscan2
- DGAT1 | c.526C>T p.L176= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100184214; called by muse, mutect2
- DGKD | c.2043G>A p.S681= (on ENST00000264057 / NM_152879.3; = p.S637= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs766370089, COSV51043586; called by muse, mutect2, varscan2
- DLC1 | c.2847G>A p.Q949= (on ENST00000276297 / NM_001348081.2; = p.Q512= on NM_006094.5) | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV52317404; called by muse, mutect2, varscan2
- DLG2 | c.1011C>T p.D337= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as rs766353037, COSV54638779, COSV54643067; called by muse, mutect2, varscan2
- DNMBP | c.378C>G p.L126= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV60629832; called by mutect2, varscan2
- DPYSL3 | c.1140C>T p.F380= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV58329049; called by muse, mutect2, varscan2
- EFCAB1 | c.21G>A p.Q7= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as rs755854932, COSV50619169; called by muse, mutect2, varscan2
- EHF | c.516C>T p.S172= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV57669258; called by muse, mutect2, varscan2
- ENGASE | c.1146C>T p.F382= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV56136792; called by muse, mutect2, varscan2
- ESPN | c.1458G>A p.K486= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100911533; called by mutect2, varscan2
- ESYT2 | c.1134G>A p.L378= (on ENST00000613624; = p.L302= on NM_020728.3) | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV51754223; called by muse, mutect2, varscan2
- FRY | c.6363C>T p.F2121= | Silent (SNP) | VAF 13/329 reads (4%) | catalogued as COSV66567623, COSV66574979; called by muse, mutect2
- GAS2L2 | c.393G>A p.L131= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- GBA2 | c.204G>A p.L68= | Silent (SNP) | VAF 15/157 reads (10%) | catalogued as rs745841775, COSV65240020; called by muse, mutect2
- GMIP | c.1767C>T p.S589= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs773205436, COSV52558437; called by muse, mutect2, varscan2
- GRIP2 | c.870G>A p.L290= (on ENST00000619221; = p.L193= on NM_001080423.4) | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99817748; called by muse, mutect2
- H2BC9 | c.138G>A p.L46= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs1473395445, COSV55100465; called by muse, mutect2, varscan2
- HHIP | c.120G>C p.L40= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1231259390, COSV56842132, COSV99666650; called by muse, mutect2, varscan2
- HMGCLL1 | c.612C>T p.H204= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs1326442322, COSV51448690; called by muse, mutect2, varscan2
- HNRNPUL2 | c.651C>T p.F217= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV53666335; called by muse, mutect2, varscan2
- INCENP | c.729C>T p.P243= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV53918838; called by muse, mutect2, varscan2
- IST1 | c.78G>C p.V26= (on ENST00000535424 / NM_001270976.1; = p.V13= on NM_014761.4) | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV61710586; called by muse, mutect2, varscan2
- KCNS3 | c.987C>G p.L329= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV58408189; called by muse, mutect2, varscan2
- KIAA1522 | c.3093G>A p.Q1031= (on ENST00000373480 / NM_001198972.2; = p.Q1090= on NM_020888.3) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV53864862, COSV53866488; called by muse, mutect2, varscan2
- KIF16B | c.3213C>T p.I1071= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV61710684; called by muse, mutect2, varscan2
- KIFBP | c.159G>T p.A53= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs781721076, COSV62556212; called by muse, mutect2, varscan2
- LAT | c.216C>G p.P72= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV57955815, COSV57956531; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.876C>T p.G292= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs779003169, COSV65419913; called by muse, mutect2, varscan2
- MAGI2 | c.3879C>T p.D1293= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs758491046, COSV100831978, COSV62682552; called by muse, mutect2, varscan2
- MARK1 | c.862C>T p.L288= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV65069757, COSV65070227; called by muse, mutect2, varscan2
- MAZ | c.633C>A p.I211= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV50716870; called by muse, mutect2, varscan2
- MINK1 | c.732C>G p.L244= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100767209, COSV61791671; called by muse, mutect2, varscan2
- MSH5 | c.2247G>A p.A749= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs527749901, COSV100991944; called by muse, mutect2
- MUC5B | c.10911C>T p.S3637= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs1405451797, COSV101500850; called by muse, mutect2, varscan2
- NCAN | c.120G>A p.Q40= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV53055106; called by muse, mutect2, varscan2
- NCAPH | c.1479G>C p.L493= | Silent (SNP) | VAF 13/170 reads (8%) | catalogued as COSV53637593; called by muse, mutect2
- NEU4 | c.855C>T p.A285= (on ENST00000391969 / NM_001167602.3; = p.A297= on NM_080741.4) | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100372222; called by muse, mutect2
- NOC2L | c.420G>A p.L140= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV58532755; called by muse, mutect2, varscan2
- NRAP | c.3240G>A p.R1080= (on ENST00000359988 / NM_001322945.2; = p.R1045= on NM_006175.4) | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV63492721; called by muse, mutect2, varscan2
- NT5DC3 | c.1440C>T p.F480= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV67321172, COSV67321557; called by muse, mutect2, varscan2
- OR3A1 | c.387C>T p.I129= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV60163558; called by muse, mutect2, varscan2
- OR4K15 | c.357T>C p.D119= (on ENST00000305051; = p.D95= on NM_001005486.1) | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV59302395; called by muse, mutect2, varscan2
- OR8H3 | c.736T>C p.L246= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as COSV57910260, COSV57912199; called by muse, mutect2, varscan2
- PCDHA4 | c.858G>A p.S286= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs150161354; called by muse, mutect2, varscan2
- PCDHGA10 | c.2118C>T p.C706= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV53993921; called by muse, mutect2, varscan2
- PCNX2 | c.864C>G p.V288= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV50839923; called by muse, mutect2, varscan2
- PDIA2 | c.813C>T p.F271= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs374179213; called by mutect2, varscan2
- PHKG2 | c.756C>T p.F252= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs778270637, COSV60313033; called by muse, mutect2, varscan2
- PIK3C3 | c.2271C>G p.L757= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV56282312; called by muse, mutect2, varscan2
- PIK3R2 | c.1407G>A p.R469= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV55849320; called by muse, mutect2, varscan2
- PPP1R9A | c.2649G>A p.L883= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV56902666; called by muse, mutect2, varscan2
- PRAMEF14 | c.196C>T p.L66= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- PRDM1 | c.861G>A p.G287= | Silent (SNP) | VAF 1725/1801 reads (96%) | catalogued as COSV64846136; called by muse, mutect2, varscan2
- RALGAPA2 | c.258C>A p.L86= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99175151; called by muse, mutect2
- RECQL4 | c.1092G>A p.V364= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs1292950539, COSV99468325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGL1 | c.1890G>A p.V630= (on ENST00000360851 / NM_001297672.2; = p.V665= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV58990889; called by muse, mutect2, varscan2
- RXRA | c.1254C>G p.L418= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs760589666, COSV62684895; called by muse, mutect2, varscan2
- SAMD9L | c.4518C>G p.L1506= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs1005620157, COSV59083616; called by muse, mutect2, varscan2
- SERINC3 | c.30C>T p.L10= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs1319024728, COSV99668025; called by muse, mutect2, varscan2
- SLC30A3 | c.564C>T p.V188= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99273930; called by muse, mutect2
- SLC7A1 | c.750C>T p.F250= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs771167957, COSV66330368; called by muse, mutect2, varscan2
- SLCO1C1 | c.690G>T p.T230= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs184790684, COSV56876598; called by muse, mutect2, varscan2
- SNAPC2 | c.489C>T p.P163= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs752865998, COSV54491284; called by muse, mutect2, varscan2
- SOX5 | c.804G>A p.Q268= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100508443; called by muse, mutect2, varscan2
- SYNE1 | c.14349C>T p.H4783= (on ENST00000367255 / NM_182961.4; = p.H4712= on NM_033071.3) | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs767810691, COSV55045155; called by muse, mutect2, varscan2
- SYNGR4 | c.348C>G p.V116= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV61225693; called by muse, mutect2, varscan2
- SYNPO2 | c.207C>T p.V69= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV61114582; called by muse, mutect2, varscan2
- TAB3 | c.528A>G p.S176= | Silent (SNP) | VAF 49/60 reads (82%) | catalogued as COSV55839159; called by muse, mutect2, varscan2
- TAGAP | c.1845G>A p.V615= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV57852688; called by muse, mutect2, varscan2
- TAS1R1 | c.1911C>G p.L637= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV59840297; called by muse, mutect2, varscan2
- TAS2R31 | c.324C>G p.L108= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV66830863; called by muse, mutect2, varscan2
- TBC1D10B | c.1017C>T p.F339= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV69505361; called by muse, mutect2, varscan2
- TFCP2 | c.1410C>T p.I470= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV56934721; called by muse, varscan2
- TMUB1 | c.330C>G p.L110= | Silent (SNP) | VAF 26/226 reads (12%) | catalogued as COSV52541295; called by muse, mutect2, varscan2
- TRAJ39 | c.27C>T p.L9= | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- TRIO | c.1884G>A p.L628= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as COSV60089442; called by muse, mutect2, varscan2
- VPS13D | c.12675G>A p.Q4225= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs771320353, COSV50659704; called by muse, mutect2, varscan2
- XKR4 | c.1671C>T p.S557= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV59323374; called by muse, mutect2, varscan2
- XPO7 | c.2517G>A p.L839= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV53017707; called by muse, mutect2, varscan2
- XRCC1 | c.1446G>A p.A482= | Silent (SNP) | VAF 59/90 reads (66%) | catalogued as rs368774314; called by muse, mutect2, varscan2
- ZBTB16 | c.1137C>T p.F379= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV60096972; called by muse, mutect2, varscan2
- ZDHHC8 | c.2079C>T p.F693= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV57711876; called by muse, mutect2, varscan2
- ZFYVE9 | c.3645C>T p.Y1215= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV55089955; called by muse, varscan2
- ZKSCAN5 | c.204C>T p.L68= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV58743734; called by muse, mutect2, varscan2
- ZNF517 | c.48C>T p.F16= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs1448571502, COSV63464822; called by muse, mutect2, varscan2
- ZPBP2 | c.546C>T p.V182= (on ENST00000348931 / NM_199321.3; = p.V160= on NM_198844.3) | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV62375491; called by muse, mutect2, varscan2
- C7orf31 | c.*1G>C | 3'UTR (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99384209; called by muse, mutect2, varscan2
- MIR379 | n.23T>C | RNA (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- PXN | c.831+1683C>T | Intron (SNP) | VAF 7/25 reads (28%) | catalogued as rs759011013; called by muse, mutect2, varscan2
- TPI1 | c.*120C>T | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99222998; called by muse, mutect2
- TRAK1 | c.1963+220G>A | Intron (SNP) | VAF 39/253 reads (15%) | catalogued as COSV58261876; called by muse, mutect2, varscan2
- TRAV36DV7 | chr14:22222457 C>G | 5'Flank (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- ZNF396 | c.*851C>T | 3'UTR (SNP) | VAF 22/82 reads (27%) | catalogued as COSV60474313; called by muse, mutect2, varscan2
